Somatic mutation profile of tumor specimen TARGET-20-PARJKM-09A (aliquot TARGET-20-PARJKM-09A-01D) from TARGET case TARGET-20-PARJKM, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.2 years (434 days).
Specimen TARGET-20-PARJKM-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eb46b6a0-ff79-47aa-ab64-3472493f7fc0.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARJKM-14A (Bone Marrow Normal), aliquot TARGET-20-PARJKM-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f746806a-158d-41ed-b360-b3e66bf2f032

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSPG4 | c.66G>A p.M22I | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs1354256466; called by muse, mutect2, varscan2
- KLHDC7B | c.539G>A p.R180Q (on ENST00000395676; = p.R821Q on NM_138433.5) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as rs775030756; called by muse, varscan2
- KLHDC7B | c.540G>A p.R180= (on ENST00000395676; = p.R821= on NM_138433.5) | Silent (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
